Surgical pathology report (de-identified scan), TCGA case TCGA-39-5037, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5037-01A (Primary Tumor).

[page 1 of 4]
CGA-39-5037

Clinical Diagnosis & History:

with DLL lesion (+) PET

Specimens Submitted:

- 1: SP: Para-aortic adventitia tissue
- 2: SP: Left lower lobe lung
- 3: SP: Left level eleven lymph node
- 4: SP: Level seven lymph node
- 5: SP: Left level ten lymph node

DIAGNOSIS:

- 1) SOFT TISSUE, PARA-AORTIC-AORTIC ADVENTITIA, EXCISION:
- BENIGN VESSEL WALL.
- 2) LUNG, LEFT LOWER LOBE, LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, MODERATELY TO POORLY DIFFERENTIATED/UNDIFFERENTIATED, OF LEFT LOWER LOBE.
- THE TUMOR MEASURES 2.3 X 2.2 X 2.0 CM.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE MAINSTEM BRONCHUS IS NOT INVOLVED BY TUMOR.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PLEURA IS FREE OF TUMOR.
- THE NON-NEOPLASTIC LUNG IS UNREMARKABLE.
- THE NON-NEOPLASTIC LUNG IS UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED):
PERIBRONCHIAL: 1/2, HILAR: 0/6.
- 3) LYMPH NODE, LEFT, LEVEL XI, EXCISION:
- BENIGN LYMPH NODE.
- 4) LYMPH NODE, LEVEL VII, EXCISION:
- BENIGN LYMPH NODE.
- 5) LYMPH NODE, LEFT LEVEL X, EXCISION:
- BENIGN LYMPH NODE.

** Continued on next page **

[page 2 of 4]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh for frozen section consultation, labeled "Para aortic adventitia" and consists of two fragments of soft tissue measuring 0.4 cm and 0.5 cm in greatest dimension, which are entirely submitted for frozen section consultation.

Summary of sections:
FSC-frozen section control

2). The specimen is received fresh, labeled, "left lower lobe lung". It consists of a 16.0 x 13.5 x 4.8 cm lung lobe with attached bronchus and blood vessels, which weighs 244 gm. There is no stapled margin. The attached bronchus measures 1.0 cm in length by 1.1 cm in diameter. There is a 5.0 x 2.0 cm surgical defect on the anterior aspect. The pleural surface shows multiple areas of fibrous adhesions. The pleural surface is inked black. Serial sectioning reveals a 2.3 x 2.2 x 2.0 cm white-tan, stellate tumor. The tumor is ill-defined. The tumor is situated in the mid lung parenchyma, located 2.2 cm from the bronchial margin. The tumor is within the parenchyma 1.2 cm from the pleura. The tumor grossly does not involve the bronchus without causing bronchial obstruction. The bronchial mucosa is smooth and glistening. There are no satellite lesions. Peribronchial anthracotic lymph nodes are identified and submitted. The uninvolved lung parenchyma is unremarkable. The bronchial margin and a representative section of tumor were sent for frozen section. Representative sections including the entire tumor are submitted. TPS is submitted. Photographs are taken.

Summary of sections:
FSCA -- frozen section control, bronchial margin.
FSCB -- frozen section control, tumor.
VM -- vascular margin.
TP -- tumor with pleura.
TB -- tumor with bronchus
TU -- tumor with adjacent pulmonary parenchyma.
RA -- random lung parenchyma at least 3 cm away from main tumor
RC -- random lung parenchyma close to tumor (within 3 cm of main tumor)
LN -- lymph nodes.

** Continued on next page **

[page 3 of 4]
3). The specimen is received in formalin, labeled "left level 11 lymph node" and consists of an anthracotic lymphoid fragment measuring 0.8 cm in greatest dimension, which is entirely submitted whole.

Summary of sections:
U-undesignated

4). The specimen is received in formalin, labeled "Level 7 lymph node" and consists of an anthracotic lymph node measuring 1 cm in greatest dimension, which is bisected and submitted entirely.

Summary of sections:
BLN - bisected lymph node

5). The specimen is received in formalin, labeled "Left level 10 lymph node" and consists of a 1.2 cm flattened anthracotic lymph node which is submitted entirely.

Summary of sections:
U-undesignated

Summary of Sections:

Part 1: SP: Para-aortic adventitia tissue

Block	Sect. Site	PCs
1	fsc	1

Part 2: SP: Left lower lobe lung

Block	Sect. Site	PCs
1	fsca	1
1	fsch	1
2	ln	2
1	ra	1
1	rc	1
2	tb	2
1	tp	1
6	tu	6
1	vm	1

Part 3: SP: Left level eleven lymph node

Block	Sect. Site	PCs
1	u	1

** Continued on next page **

[page 4 of 4]
Part 4: SP: Level seven lymph node [REDACTED]

Block	Sect.	Site	PCs
1		bln	1

Part 5: SP: Left level ten lymph node [REDACTED]

Block	Sect.	Site	PCs
1		u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: PARA-AORTIC AVENT TISSUE. BENIGN
SMOOTH MUSCLE. [REDACTED]
PERMANENT DIAGNOSIS: SAME

2A) FROZEN SECTION DIAGNOSIS: LEFT LOWER LOBE LUNG. BENIGN
BRONCHIAL MARGIN. [REDACTED]
PERMANENT DIAGNOSIS: SAME

2B) FROZEN SECTION DIAGNOSIS: LEFT LOWER LOBE LUNG. POORLY
DIFFERENTIATED SQUAMOUS CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME

[REDACTED]

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: PARA-AORTIC AVENT TISSUE. BENIGN
SMOOTH MUSCLE. [REDACTED]
PERMANENT DIAGNOSIS: SAME

2A) FROZEN SECTION DIAGNOSIS: LEFT LOWER LOBE LUNG. BENIGN
BRONCHIAL MARGIN. [REDACTED]
PERMANENT DIAGNOSIS: SAME

2B) FROZEN SECTION DIAGNOSIS: LEFT LOWER LOBE LUNG. POORLY
DIFFERENTIATED SQUAMOUS CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file b6cff13b-4835-483b-b5a5-3408103211f6 (TCGA-39-5037.7A100E58-1E99-48B4-9DB1-0228AAF4BB71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).